Somatic mutation profile of tumor specimen TCGA-AJ-A23M-01A (aliquot TCGA-AJ-A23M-01A-11D-A159-09) from TCGA case TCGA-AJ-A23M, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 61.4 years (22,430 days).
Specimen TCGA-AJ-A23M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33e35af6-e7ff-4941-9211-8fc892e7b7d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A23M-10A (Blood Derived Normal), aliquot TCGA-AJ-A23M-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dea1de6-938d-49ba-91b9-3421e51ace03

The open-access MAF lists 117 somatic variants for this specimen: 83 protein-altering or splice-affecting, 33 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 33, Nonsense Mutation 9, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1, In Frame Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.828_830dup p.C277dup | In Frame Ins (INS) | VAF 28/39 reads (72%) | hotspot (GDC flag); catalogued as COSV52732498, COSV53820152; called by mutect2, pindel, varscan2
- A4GNT | c.761T>A p.F254Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as COSV52629501; called by muse, mutect2, varscan2
- ABCB1 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV55956663; called by muse, mutect2, varscan2
- ABCG4 | c.774C>G p.H258Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV56644702; called by muse, mutect2, varscan2
- ACSM4 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV68066637; called by muse, mutect2, varscan2
- AIG1 | c.106G>T p.G36* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV51629972; called by muse, mutect2
- ARHGEF6 | c.1946-1G>T p.X649_splice | Splice Site (SNP) | VAF 24/87 reads (28%) | catalogued as COSV51693556; called by muse, mutect2, varscan2
- ATP6V1E1 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV53658620; called by muse, mutect2, varscan2
- B4GALNT3 | c.1530G>C p.Q510H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV99842422; called by muse, mutect2
- BSX | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as rs868246509, COSV58005485, COSV58005909; called by muse, mutect2, varscan2
- CACNA1A | c.4699G>A p.V1567M | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV64204533; called by muse, mutect2, varscan2
- CADPS | c.2338G>C p.E780Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.986); catalogued as COSV51890805; called by muse, mutect2, varscan2
- CCDC170 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV53343348; called by muse, mutect2, varscan2
- CFTR | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV50071897; called by muse, mutect2, varscan2
- CHD1 | c.4174C>T p.H1392Y | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV52342570; called by muse, mutect2, varscan2
- CNBD1 | c.787A>T p.T263S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV73074148; called by muse, mutect2, varscan2
- COL11A1 | c.5221G>A p.E1741K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1177996327, COSV100618361, COSV62189636; called by muse, mutect2, varscan2
- COL11A1 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62189641; called by muse, mutect2, varscan2
- COL4A6 | c.1989C>G p.Y663* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | catalogued as COSV100563316, COSV57868368; called by muse, mutect2, varscan2
- COLEC11 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs767854958, COSV52595437; called by muse, mutect2, varscan2
- DNAH7 | c.6429T>G p.D2143E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV56774499; called by muse, mutect2, varscan2
- DPEP3 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); catalogued as rs1456389727, COSV52051982; called by muse, mutect2, varscan2
- EDEM3 | c.1856C>G p.S619* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV58926165; called by muse, mutect2, varscan2
- ELOVL2 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV61156191; called by muse, mutect2, varscan2
- F13B | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66374765; called by muse, mutect2
- FAM120B | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.424); catalogued as COSV53006169; called by muse, mutect2, varscan2
- FBXO15 | c.228A>C p.G76= | Splice Region (SNP) | VAF 18/57 reads (32%) | catalogued as COSV54046923, COSV99503385; called by muse, mutect2, varscan2
- FGD6 | c.1700G>T p.W567L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59694971; called by muse, mutect2, varscan2
- GATA3 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs201023943, COSV60518691, COSV60521826; called by muse, mutect2, varscan2
- GNL3L | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV60577062; called by muse, mutect2, varscan2
- GOLM2 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55464835; called by muse, mutect2, varscan2
- GPRASP1 | c.2884G>C p.E962Q | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.408); catalogued as COSV64356070; called by muse, mutect2, varscan2
- INO80 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV100732020, COSV62740232; called by muse, mutect2, varscan2
- IPO9 | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV64233805, COSV64234598; called by muse, mutect2, varscan2
- KAT2A | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782474058, COSV52427011; called by muse, mutect2, varscan2
- KATNIP | c.2352G>C p.W784C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55185948; called by muse, mutect2, varscan2
- KIF5A | c.345C>A p.D115E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54056711; called by muse, mutect2, varscan2
- KIRREL1 | c.1037C>G p.S346* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV63289241; called by muse, mutect2, varscan2
- KRT71 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57291243, COSV57291891; called by muse, mutect2, varscan2
- LRPAP1 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99578777; called by muse, mutect2
- LRRC41 | c.1953C>A p.F651L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV58441002; called by muse, mutect2, varscan2
- LUZP4 | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.025); catalogued as COSV64219301; called by mutect2, varscan2
- MAS1L | c.896T>G p.I299S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as COSV65809247; called by muse, mutect2, varscan2
- MGA | c.7312G>T p.E2438* (on ENST00000219905 / NM_001164273.1; = p.E2229* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV54953260; called by muse, mutect2, varscan2
- MLX | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV53817921; called by muse, mutect2, varscan2
- MUC17 | c.12755T>G p.L4252R | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV60295641; called by muse, mutect2, varscan2
- MYO3A | c.2763G>A p.M921I | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV56339211; called by muse, mutect2, varscan2
- NCBP1 | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV64316431, COSV64317104; called by muse, mutect2, varscan2
- NDUFAF4 | c.260G>A p.C87Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV60214382; called by muse, mutect2, varscan2
- NRXN1 | c.4010A>T p.K1337M | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV60509646; called by muse, mutect2, varscan2
- NRXN2 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1421828683, COSV55452013; called by muse, mutect2
- OR4K1 | c.244del p.V83* | Frame Shift Del (DEL) | VAF 62/103 reads (60%) | catalogued as COSV53461276; called by mutect2, pindel, varscan2
- PDCD1 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs368829632, COSV99044110; called by muse, mutect2, varscan2
- PGM2L1 | c.939+1G>T p.X313_splice | Splice Site (SNP) | VAF 19/64 reads (30%) | catalogued as COSV53348136; called by muse, mutect2, varscan2
- PIK3CA | c.3085G>C p.D1029H | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as COSV55889750, COSV55906105, COSV56009988; called by muse, mutect2, varscan2
- PIK3R1 | c.1156C>T p.R386* (on ENST00000521381 / NM_181523.3; = p.R116* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 55/87 reads (63%) | catalogued as COSV57126203, COSV57144628; called by muse, mutect2, varscan2
- PLP2 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100889947, COSV66235123; called by muse, mutect2, varscan2
- PLPP3 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100984560; called by muse, mutect2
- POLE4 | c.299-1G>T p.X100_splice | Splice Site (SNP) | VAF 73/170 reads (43%) | catalogued as COSV52051480; called by muse, mutect2, varscan2
- POLR2F | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100704019; called by muse, mutect2, varscan2
- PRPF6 | c.2414A>C p.Q805P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53874405; called by muse, mutect2
- RANBP6 | c.154T>C p.F52L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV52390434; called by muse, mutect2, varscan2
- REXO5 | c.134C>A p.A45D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV54473387; called by muse, mutect2, varscan2
- RNF214 | c.1753C>G p.R585G | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56119982, COSV56120060; called by muse, mutect2, varscan2
- SATB1 | c.1585T>G p.C529G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58671175; called by muse, mutect2, varscan2
- SLC39A4 | c.1453G>T p.E485* (on ENST00000301305 / NM_001374839.1; = p.E460* on NM_017767.3) | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99432983; called by muse, mutect2
- SLC9A1 | c.2054C>T p.T685M | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs140853773, COSV56057330; called by mutect2, varscan2
- SPICE1 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99870848; called by muse, mutect2, varscan2
- SUMF2 | c.536G>T p.G179V (on ENST00000652303; = p.G160V on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV51917776; called by muse, mutect2, varscan2
- TBC1D8 | c.991A>G p.S331G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100964281; called by muse, mutect2
- THRAP3 | c.2089A>G p.K697E | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as COSV63568843; called by muse, mutect2, varscan2
- TMEM132D | c.2464G>T p.V822F | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV67161234; called by muse, mutect2, varscan2
- TRAF3IP2 | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100389616; called by mutect2, varscan2
- TRIM46 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV58116667; called by muse, mutect2
- TSPAN6 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV65957445; called by muse, mutect2, varscan2
- USP54 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.233); catalogued as COSV60444905; called by muse, mutect2, varscan2
- ZC3H6 | c.3272G>C p.G1091A | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV59669317; called by muse, mutect2, varscan2
- ZNF286A | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV67846001; called by muse, mutect2, varscan2
- ARHGAP35 | c.2978dup p.Y993* | Nonsense Mutation (INS) | VAF 14/28 reads (50%) | called by mutect2, varscan2
- BCL2L11 | c.561dup p.R188Tfs*77 (on ENST00000393256 / NM_138621.5; = p.R128Tfs*77 on NM_006538.5) | Frame Shift Ins (INS) | VAF 36/100 reads (36%) | called by mutect2, pindel, varscan2
- MKRN1 | c.298del p.Y100Mfs*13 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- MRC1 | c.3902G>C p.R1301T | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PRAMEF15 | c.987C>G p.D329E | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- A4GNT | c.762C>T p.F254= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs369495396; called by muse, mutect2, varscan2
- ABCA13 | c.3141C>T p.F1047= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV70035681; called by muse, mutect2, varscan2
- API5 | c.1407T>A p.S469= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV66634087; called by muse, mutect2, varscan2
- CD68 | c.225G>A p.T75= | Silent (SNP) | VAF 30/208 reads (14%) | catalogued as rs1409546478, COSV51511379; called by muse, mutect2, varscan2
- CEP57L1 | c.504G>A p.L168= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV61245314; called by muse, mutect2, varscan2
- CILP | c.882G>T p.L294= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV56026059, COSV56028552; called by muse, mutect2, varscan2
- COL12A1 | c.8535A>G p.G2845= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV100485393; called by muse, mutect2
- DHCR24 | c.969C>G p.P323= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as rs1236586416, COSV64875134; called by muse, mutect2, varscan2
- ESYT1 | c.315G>T p.A105= | Silent (SNP) | VAF 31/168 reads (18%) | catalogued as COSV57274810; called by muse, mutect2, varscan2
- FGD1 | c.786C>A p.S262= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV64309165; called by muse, mutect2, varscan2
- GRM1 | c.2751G>A p.V917= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99263969; called by muse, mutect2
- HEXA | c.243T>G p.P81= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV51507507; called by muse, mutect2
- ITPR3 | c.7584G>A p.Q2528= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV65268662; called by muse, mutect2, varscan2
- KCNMA1 | c.2580G>T p.L860= (on ENST00000286628 / NM_001161352.2; = p.L802= on NM_002247.4) | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV54265796; called by muse, mutect2, varscan2
- MCHR2 | c.861T>C p.G287= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs751631867, COSV56005632; called by muse, mutect2, varscan2
- MYOM2 | c.3477C>T p.T1159= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs755269688, COSV50715236, COSV50733425; called by muse, mutect2, varscan2
- OR5D18 | c.168G>T p.L56= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV61737892; called by muse, mutect2, varscan2
- PDE1A | c.1608T>A p.A536= | Silent (SNP) | VAF 42/192 reads (22%) | catalogued as COSV59528985; called by muse, mutect2, varscan2
- PICALM | c.1365A>G p.V455= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1351383888, COSV62671905; called by muse, mutect2, varscan2
- PRPF4B | c.1992C>G p.L664= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV61783270; called by muse, mutect2, varscan2
- R3HCC1L | c.783C>T p.S261= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs772469875, COSV54403335; called by muse, mutect2, varscan2
- RNF43 | c.573C>T p.P191= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV68459139; called by muse, mutect2, varscan2
- SHOX2 | c.846C>T p.F282= (on ENST00000441443 / NM_006884.3; = p.F306= on NM_003030.4) | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV67464257; called by muse, mutect2, varscan2
- SLC25A36 | c.867G>C p.V289= (on ENST00000324194 / NM_001104647.3; = p.V288= on NM_018155.3) | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as COSV60782564; called by muse, mutect2, varscan2
- SLC6A3 | c.1194C>A p.I398= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs765232850, COSV54366671; called by muse, mutect2, varscan2
- SLITRK3 | c.1761T>C p.G587= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV53850683; called by muse, mutect2, varscan2
- SULT1E1 | c.126T>C p.I42= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99894672; called by muse, mutect2, varscan2
- TET2 | c.2337T>C p.T779= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV54421895; called by muse, mutect2
- TLDC2 | c.579C>T p.F193= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1290239907, COSV53430953; called by muse, mutect2, varscan2
- TMEM164 | c.75G>T p.G25= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV55813970; called by muse, mutect2
- TMEM86B | c.345C>T p.F115= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs377582693; called by muse, mutect2, varscan2
- TTN | c.96858T>G p.L32286= (on ENST00000591111; = p.L24862= on NM_003319.4) | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100593810; called by muse, mutect2
- WSB1 | c.1131T>C p.F377= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV52216122; called by muse, mutect2, varscan2
- PYY3 | n.9G>A | RNA (SNP) | VAF 31/75 reads (41%) | catalogued as rs367834597; called by muse, mutect2, varscan2
